Gene-level copy-number profile of tumor specimen ALCH-B2P5-TTP1-A from ALCHEMIST case ALCH-B2P5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.6 years (23,948 days).
Specimen ALCH-B2P5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c8d42844-e611-482f-af69-6f4a3e9a9c33.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2P5-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/36a4604f-6737-4a1a-bea7-e6f813a763c4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 82; copy number 1: 3,214; copy number 2: 55,484; copy number 3: 93; copy number 4: 35; copy number 5: 3; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:241,637,213–241,673,857, 1 gene (within-gene range 0–2): ATG4B.
- chr7:74,606,913–74,633,884, 2 genes: AC211433.2, AC211433.3.
- chr15:25,170,723–25,241,827, 39 genes (within-gene range 0–2): SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39.
- chr17:2,724,411–2,749,504, 1 gene (within-gene range 0–2): CCDC92B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:163,413,065–163,413,960, 1 gene, copy number 5: CAHM.
- chr19:1,228,287–1,244,825, 3 genes, copy number 5–7 (within-gene range 3–7): CBARP, AC004221.1, ATP5F1D.

Autosomal genes at a single copy (total copy number 1): 514. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
